Somatic mutation profile of tumor specimen TCGA-ZF-AA4R-01A (aliquot TCGA-ZF-AA4R-01A-11D-A38G-08) from TCGA case TCGA-ZF-AA4R, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 67.2 years (24,537 days).
Specimen TCGA-ZF-AA4R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ce8a6f4-5bc9-4caf-9eaa-25739052ea36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZF-AA4R-10A (Blood Derived Normal), aliquot TCGA-ZF-AA4R-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8304eb09-4428-4a42-bb1a-9d7cd548fb03

The open-access MAF lists 69 somatic variants for this specimen: 53 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 14, Nonsense Mutation 4, Frame Shift Del 4, Frame Shift Ins 2, Intron 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2301C>G p.I767M | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54064925; called by muse, mutect2
- SF3B1 | c.2705A>G p.E902G | Missense Mutation (SNP) | VAF 20/37 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59225586; called by muse, mutect2, varscan2
- AL163636.1 | c.37G>A p.V13M | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59013106; called by muse, mutect2, varscan2
- AMPD1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as COSV62418585; called by muse, mutect2, varscan2
- ANAPC2 | c.1958G>A p.R653H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs777263918, COSV60572162; called by muse, mutect2, varscan2
- ARID4A | c.2432C>T p.S811L | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.054); catalogued as rs761464174, COSV62163001; called by muse, mutect2, varscan2
- AXIN2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1244431726, COSV100195707; called by muse, mutect2
- CDK12 | c.1190C>T p.A397V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV101420219, COSV101420472; called by muse, mutect2
- CEBPA | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57199425, COSV57201318; called by muse, mutect2, varscan2
- CIT | c.142C>G p.R48G | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as rs779825114, COSV55862996, COSV55881521; called by muse, mutect2
- CREBBP | c.4301T>G p.L1434R | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52125476, COSV52127962, COSV52138863; called by muse, mutect2
- CRISPLD1 | c.528T>A p.S176R | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV51552613; called by muse, mutect2, varscan2
- CSAG1 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.74); catalogued as COSV63401134; called by muse, mutect2, varscan2
- DDX19B | c.577A>C p.K193Q | Missense Mutation (SNP) | VAF 10/190 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV55365942; called by muse, mutect2
- DIP2A | c.1514C>A p.T505K | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV59486003; called by muse, mutect2
- ENAM | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as COSV68536858; called by muse, mutect2, varscan2
- FER1L6 | c.2299C>T p.R767* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs553419499, COSV67548308; called by muse, mutect2, varscan2
- GZMK | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 125/182 reads (69%) | catalogued as COSV99140817; called by muse, mutect2, varscan2
- H2BC21 | c.25C>G p.P9A | Missense Mutation (SNP) | VAF 173/215 reads (80%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.147); catalogued as COSV58611973, COSV58613463; called by muse, mutect2, varscan2
- HK2 | c.2365C>T p.Q789* | Nonsense Mutation (SNP) | VAF 18/95 reads (19%) | catalogued as COSV99308380, COSV99309693; called by muse, mutect2, varscan2
- KBTBD7 | c.256C>G p.R86G | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65267096; called by muse, mutect2, varscan2
- KIAA0753 | c.2714G>A p.R905H | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as rs61735434, COSV63818829; called by muse, mutect2, varscan2
- KIAA1143 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.027); catalogued as COSV99941506; called by muse, mutect2, varscan2
- LRRC34 | c.926A>C p.D309A (on ENST00000446859 / NM_001172779.2; = p.D277A on NM_153353.5) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV57187826; called by muse, mutect2, varscan2
- MAGEC1 | c.1383T>G p.S461R | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.238); catalogued as COSV53580310; called by muse, mutect2, varscan2
- MEF2A | c.650G>C p.G217A (on ENST00000557942 / NM_001319206.2; = p.G219A on NM_005587.4 and 8 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as COSV57536950; called by muse, mutect2, varscan2
- MUC5B | c.13151C>G p.S4384C | Missense Mutation (SNP) | VAF 39/124 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV71594975; called by muse, mutect2, varscan2
- NDUFA8 | c.148G>C p.E50Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV65653640; called by muse, mutect2, varscan2
- NOL8 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as rs1485704799, COSV62637740; called by muse, mutect2, varscan2
- NUP205 | c.1510C>G p.L504V | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53665356; called by muse, mutect2, varscan2
- OR2AG1 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56625541, COSV56627421; called by muse, mutect2, varscan2
- OR2T6 | c.533T>A p.F178Y | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV63216983; called by muse, mutect2
- OSR1 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV55346438; called by muse, mutect2, varscan2
- PAK2 | c.493C>G p.P165A | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV59084896; called by muse, mutect2, varscan2
- PARP14 | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV72111685, COSV72111778; called by muse, mutect2, varscan2
- PRDM9 | c.1675C>T p.R559W | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs746973453, COSV57003391, COSV57006333; called by muse, mutect2, varscan2
- RECQL5 | c.771G>T p.G257= | Splice Region (SNP) | VAF 67/282 reads (24%) | catalogued as COSV53130132; called by muse, mutect2, varscan2
- S100PBP | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.037); catalogued as COSV63140537; called by muse, mutect2, varscan2
- SLC9C2 | c.597dup p.G200Wfs*14 | Frame Shift Ins (INS) | VAF 24/105 reads (23%) | catalogued as rs760633653; called by mutect2, varscan2
- SMC4 | c.3028G>C p.D1010H | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as COSV59088410; called by muse, mutect2, varscan2
- TMEM168 | c.1021G>C p.D341H | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV57179471; called by muse, mutect2, varscan2
- TRPM3 | c.1222A>T p.T408S (on ENST00000357533 / NM_001366142.2; = p.T253S on NM_020952.6) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as COSV62593677; called by muse, mutect2, varscan2
- TTN | c.57304G>A p.V19102M (on ENST00000591111; = p.V11678M on NM_003319.4) | Missense Mutation (SNP) | VAF 29/43 reads (67%) | PolyPhen probably damaging (0.999); catalogued as rs1443853976, COSV60306067; called by muse, mutect2, varscan2
- TTN | c.50300C>A p.P16767Q (on ENST00000591111; = p.P9343Q on NM_003319.4) | Missense Mutation (SNP) | VAF 9/81 reads (11%) | PolyPhen probably damaging (0.999); catalogued as COSV60306119; called by muse, mutect2, varscan2
- VAMP8 | c.248T>C p.I83T | Missense Mutation (SNP) | VAF 122/289 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as rs1478541162, COSV55705876; called by muse, mutect2, varscan2
- ZSCAN20 | c.95C>G p.S32* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100792451; called by mutect2, varscan2
- EFCAB5 | c.3933_3934del p.L1312Rfs*3 | Frame Shift Del (DEL) | VAF 18/68 reads (26%) | called by mutect2, pindel, varscan2
- IGHG1 | c.52A>T p.T18S | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- MLXIPL | c.1099del p.D367Tfs*6 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- NEUROD2 | c.1088_1091del p.M363Tfs*181 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | called by mutect2, varscan2
- PTMA | c.233_234dup p.E79Mfs*42 (on ENST00000341369 / NM_001099285.2; = p.E78Mfs*42 on NM_002823.5) | Frame Shift Ins (INS) | VAF 13/36 reads (36%) | called by mutect2, pindel, varscan2
- SUPT20H | c.1397_1400del p.I466Nfs*83 (on ENST00000350612 / NM_001014286.3; = p.I467Nfs*83 on NM_017569.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- ZFAT | c.2885_2887del p.D962del | In Frame Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- CCDC88C | c.3546G>A p.S1182= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs771345343, COSV66237273; called by muse, mutect2
- CDC45 | c.537C>A p.A179= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as COSV54248290; called by muse, mutect2
- EPN1 | c.1584C>T p.L528= (on ENST00000270460 / NM_001321263.1; = p.L502= on NM_013333.3) | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV50043430; called by muse, mutect2, varscan2
- EXOC6 | c.966G>A p.S322= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs534862457, COSV53318998; called by muse, mutect2, varscan2
- GPRC5D | c.675G>A p.L225= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV57433390; called by muse, mutect2, varscan2
- KIAA1143 | c.45G>T p.P15= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV99941508; called by muse, mutect2
- MYF6 | c.126C>A p.S42= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as COSV57353119; called by muse, mutect2, varscan2
- NCOR1 | c.3816G>A p.L1272= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV51993814; called by muse, mutect2, varscan2
- NFASC | c.2481C>T p.A827= (on ENST00000339876 / NM_001378329.1; = p.A930= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV58378479; called by muse, mutect2, varscan2
- OR8B2 | c.315C>G p.L105= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV66665339; called by muse, mutect2
- TTN | c.83007C>T p.F27669= (on ENST00000591111; = p.F20245= on NM_003319.4) | Silent (SNP) | VAF 16/93 reads (17%) | catalogued as rs1267148835, COSV60306028; called by muse, mutect2, varscan2
- ZACN | c.453C>T p.L151= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as rs1478885447, COSV58037728; called by muse, mutect2, varscan2
- ZBTB40 | c.864A>G p.G288= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV65145176; called by muse, mutect2, varscan2
- ZNF609 | c.3495C>T p.R1165= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV58589359; called by muse, mutect2, varscan2
- DNM1 | c.1335+1738T>C | Intron (SNP) | VAF 13/41 reads (32%) | catalogued as COSV57855671; called by muse, mutect2, varscan2
- NACA | c.70+3290T>C | Intron (SNP) | VAF 3/21 reads (14%) | catalogued as COSV100771014; called by muse, mutect2
